Somatic mutation profile of tumor specimen ALCH-AD75-TTR1-A (aliquot ALCH-AD75-TTR1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-AD75, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,876 days).
Specimen ALCH-AD75-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa131a67-1fb3-458c-837e-5cee7db9d682.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD75-NB1-A (Blood Derived Normal), aliquot ALCH-AD75-NB1-A-1-0-D-A509-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ef4e9f5-8831-4aa5-a7d3-03f36f9ebe6f

The open-access MAF lists 80 somatic variants for this specimen: 49 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, Intron 5, Nonsense Mutation 4, Splice Site 2, 3'UTR 2, RNA 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 288/971 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 61/223 reads (27%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRACD | c.1774C>G p.P592A | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907183617; called by muse, mutect2
- DNAH17 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 54/552 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as rs777329899, COSV67752513; called by muse, mutect2
- ELL3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.38); catalogued as rs1282726313; called by muse, mutect2
- EXOSC10 | c.2356G>A p.D786N (on ENST00000376936 / NM_001001998.3; = p.D761N on NM_002685.4) | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.234); catalogued as rs952090050, COSV58664741; called by muse, mutect2
- FHAD1 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 78/723 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770643908, COSV58990308; called by muse, mutect2, varscan2
- IDH3B | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 103/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886043702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/944 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1386260978, COSV65368626; called by muse, mutect2
- KLRC3 | c.654C>A p.D218E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV67251580; called by muse, mutect2
- LRP2 | c.10558G>A p.A3520T | Missense Mutation (SNP) | VAF 51/778 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs138608585; called by muse, mutect2
- NPY1R | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56715555; called by muse, mutect2, varscan2
- OGDHL | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 65/470 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs757087426, COSV65105583; called by muse, mutect2, varscan2
- PGK2 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs186743372; called by muse, mutect2
- PLEKHM2 | c.60+1G>T p.X20_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | catalogued as rs113017443; called by muse, mutect2, varscan2
- TONSL | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 60/614 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs771375609, COSV68047562; called by muse, mutect2
- ABCA2 | c.784C>G p.P262A (on ENST00000614293; = p.P232A on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); called by muse, mutect2
- AFAP1 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 41/662 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- ARHGAP25 | c.607G>A p.G203R (on ENST00000409202 / NM_001007231.3; = p.G195R on NM_014882.3) | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- B3GNT2 | c.938G>C p.G313A | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CDH12 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CERCAM | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 40/634 reads (6%) | called by muse, mutect2
- COG2 | c.925T>C p.Y309H | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CXorf38 | c.761T>A p.I254K | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- ELP1 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 58/879 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.329); called by muse, mutect2
- ENTR1 | c.677C>T p.S226F (on ENST00000357365 / NM_001039707.2; = p.S203F on NM_006643.4) | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ERF | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.587); called by muse, mutect2
- FAM234A | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 97/787 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83C | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- GAP43 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- GARS1 | c.1790A>G p.E597G | Missense Mutation (SNP) | VAF 44/541 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- GRIK1 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAS1 | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2
- HAVCR2 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HERC1 | c.6875C>T p.S2292L | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NOMO2 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 44/1144 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NTRK1 | c.2018G>C p.R673T | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- NUS1 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- OGT | c.884del p.A295Vfs*5 | Frame Shift Del (DEL) | VAF 30/320 reads (9%) | called by mutect2, pindel
- PARS2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2
- PDZD4 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RAD51B | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); called by muse, mutect2
- RCC1 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2
- SCN11A | c.3057G>T p.L1019F | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ST6GALNAC6 | c.26+2T>G p.X9_splice | Splice Site (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- STYK1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRPC1 | c.1433A>G p.N478S (on ENST00000476941 / NM_001251845.2; = p.N444S on NM_003304.4) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- TSHZ3 | c.2656A>C p.T886P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2
- ZFYVE26 | c.2937C>A p.C979* | Nonsense Mutation (SNP) | VAF 52/930 reads (6%) | called by muse, mutect2
- BMPR2 | c.1593G>C p.L531= | Silent (SNP) | VAF 70/625 reads (11%) | called by muse, mutect2, varscan2
- DNAH11 | c.622A>C p.R208= | Silent (SNP) | VAF 70/312 reads (22%) | called by muse, mutect2, varscan2
- ERAL1 | c.931C>T p.L311= | Silent (SNP) | VAF 75/447 reads (17%) | catalogued as COSV54740437; called by muse, mutect2, varscan2
- FLG | c.1374A>G p.S458= | Silent (SNP) | VAF 42/835 reads (5%) | catalogued as rs1557881605; called by muse, mutect2
- GDE1 | c.318G>A p.G106= | Silent (SNP) | VAF 18/312 reads (6%) | catalogued as rs1178849790; called by muse, mutect2
- IBA57 | c.135A>T p.G45= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- IFI27L2 | c.336T>C p.N112= | Silent (SNP) | VAF 31/258 reads (12%) | called by muse, mutect2, varscan2
- ISY1-RAB43 | c.342C>A p.V114= | Silent (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- KIF14 | c.4875C>T p.V1625= | Silent (SNP) | VAF 24/322 reads (7%) | called by muse, mutect2
- NAPSA | c.1050C>T p.G350= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV53798317; called by mutect2, varscan2
- OR13A1 | c.423C>T p.Y141= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs1324546991, COSV100980963; called by muse, mutect2
- PCDHB14 | c.195G>C p.R65= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- PGP | c.276C>T p.P92= | Silent (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- PKD1 | c.7929C>T p.R2643= | Silent (SNP) | VAF 82/1642 reads (5%) | called by muse, mutect2
- PTPN14 | c.1986C>T p.H662= | Silent (SNP) | VAF 24/180 reads (13%) | called by muse, varscan2
- RETNLB | c.18C>T p.C6= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- SCN5A | c.447C>A p.A149= | Silent (SNP) | VAF 34/404 reads (8%) | called by muse, mutect2
- TLN1 | c.5136C>T p.L1712= | Silent (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- TMEM143 | c.123C>T p.P41= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs1347594938; called by muse, mutect2, varscan2
- VAT1L | c.450G>A p.P150= | Silent (SNP) | VAF 111/1033 reads (11%) | catalogued as rs369885557; called by muse, mutect2, varscan2
- AC005400.1 | n.87-20750G>A | Intron (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- AC011487.2 | n.1288A>T | RNA (SNP) | VAF 48/542 reads (9%) | called by muse, mutect2
- C19orf12 | c.24-37C>T | Intron (SNP) | VAF 31/532 reads (6%) | called by muse, mutect2
- FAM71D | c.159+688G>A | Intron (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- GLOD4 | chr17:783255 G>T | 5'Flank (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- KIF5A | c.3020+35G>T | Intron (SNP) | VAF 36/433 reads (8%) | catalogued as rs770352893; called by muse, mutect2
- KLF6 | c.*1289G>T | 3'UTR (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- KLF6 | c.*1288G>T | 3'UTR (SNP) | VAF 23/172 reads (13%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+1041C>T | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- SCNN1D | c.-109C>G | 5'UTR (SNP) | VAF 29/556 reads (5%) | catalogued as COSV57641309; called by muse, mutect2
- SLC9A7P1 | n.319C>T | RNA (SNP) | VAF 36/513 reads (7%) | called by muse, mutect2
